Surgical pathology report (de-identified scan), TCGA case TCGA-CN-5356, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-5356-01A (Primary Tumor).

[page 1 of 6]
[REDACTED] FINAL

Report Type Pathology Report

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Malignant neoplasm of larynx.

PROCEDURE: Laryngectomy.

SPECIFIC CLINICAL QUESTION: Not given.

OUTSIDE TISSUE DIAGNOSIS: Not given.

PRIOR MALIGNANCY: Not given.

CHEMORADIATION THERAPY: Not given.

ORGAN TRANSPLANT: Not given.

IMMUNOSUPPRESSION: Not given.

[REDACTED] DISEASES: Not given.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT, LEVEL 2, 3 AND 4, NECK DISSECTION
SIXTY-ONE BENIGN LYMPH NODES.

PART 2: LYMPH NODES, LEFT, LEVEL 2, 3 AND 4, NECK DISSECTION
THIRTY-SIX BENIGN LYMPH NODES.

PART 3: LARYNX AND THYROID GLAND, TOTAL LARYNGECTOMY AND RIGHT THYROID
LOBECTOMY

A. INVASIVE, MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
OF THE
SUPRAGLOTTIC REGION PREDOMINANTLY ON THE RIGHT SIDE AND WITH INVASION
OF THE
PRE-EPIGLOTTIC SPACE, 4.5 CM.

B. TUMOR ASSOCIATED ACUTE ABCESS FORMATION

C. MARGINS FREE OF TUMOR.

D. NO PERINEURAL INVASION SEEN.

E. PRESENCE OF A TRACHEOSTOMY.

F. RIGHT THYROID LOBE WITH FOCAL FIBROSIS.

G. pT3 N0 MX.

PART 4: LARYNX, RIGHT LATERAL MARGIN
NO TUMOR SEEN.

PART 5: LARYNX, LEFT LATERAL MARGIN
NO TUMOR SEEN.

PART 6: LARYNX, INFERIOR MARGIN
NO TUMOR SEEN.

PART 7: LARYNX, RIGHT SUPERIOR MARGIN
NO TUMOR SEEN.

PART 8: LARYNX, LEFT SUPERIOR MARGIN
O TUMOR SEEN.

[REDACTED]

[page 2 of 6]
My si [REDACTED] station that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received fresh in eight parts.

Part 1 is labeled with the patient's name, initials, xx, and "right neck

levels 2, 3, and 4". The specimen is received unoriented and measures 14.0 x

5.5 x 3.0 cm. It contains nodules ranging from 0.4 to 3.2 cm. All the nodules are submitted.

Cassette code:

1A 1J nodules from the first third

1A one lymph node, 3.2 cm

1B one lymph node, 2.2 cm

1C one lymph node, 2.0 cm

1D 1E one lymph node, 2.8 cm

1F 1J multiple lymph nodes

1K 1N lymph nodes from second third

1K one lymph node, 2.0 cm

1L 1N multiple lymph nodes

10 1T multiple lymph nodes from last third

10 one lymph node, 2.8 cm

1P 1T multiple lymph nodes.

Part 2 is labeled with the patient's name, initials, xx, and "left neck levels

2, 3, and 4". The specimen is received unoriented and measures 13.0 x 5.4 x

2.5 cm. It contains nodules ranging from 0.4 to 2.0 cm. All the nodules found

are submitted.

Cassette code:

2A 2B one lymph node, 2.0 cm, from first third

2C 2D multiple lymph nodes from first third

2E 2H multiple lymph nodes from second third

2I 2L multiple lymph nodes from last third.

Part 3 is received labeled with the patient's name, initials, xx, and "larynx". It measures 10.0 cm (SI) x 9.0 (L) x 6.5 (AP). Skin is present on

the anterior side with a central opening that is communicating with the trachea. The right and left supraglottic region and almost the entire epiglottis are involved by a white-gray, firm lesion of 4.5 (SI) x 2.5 (L) x

2.2 (AP). This lesion is at 0.2 cm from the right anterior margin, at 0.3 cm

from the right lateral margin, at 5.0 cm from the trachea, 0.8 cm from the

left lateral margin and at 0.9 cm from the left anterior margin. A 4.5 x 2.5

x 1.5 cm right thyroid lobe is also present. Its parenchyma is red, homogeneous and does not contain any lesions.

Digital images are taken.

Cassette code:

3A shave trachea margin

3B shave left anterior margin

[page 3 of 6]
3C shave then perpendicular right anterior margin
3D 3H right larynx, full section (D epiglottis upper, 3E epiglottis lower,
3F vocal cords, 3G soft tissue anterior to vocal cords, 3H inferior)
3I 3J lateral right margin
3K right thyroid lobe, representative section
3L 3O left larynx full section (3L epiglottis superior, 3M epiglottis lower, 3N vocal cords, 3O inferior section)
3P left lateral margin,
3Q lymph node? left anterior soft tissue
Part 4 is labeled with the patient's name, initials, xx, and "right lateral margin, stitch superior". It consists of a tan-pink fragment of 6.0 x 0.5 x 0.2 cm. The side identified by a stitch is inked blue. The specimen is submitted totally in cassette labeled 4AFS.
Part 5 is labeled with the patient's name, initials, xx and "left lateral margin". It consists of a tan-pink fragment, 4.3 x 0.2 x 0.3 cm. A clip identifies the superior side and this region is inked blue. The specimen is totally submitted in cassette labeled 5AFS.
Part 6 is labeled with the patient's name, initials, xx and "inferior margin". The tan-pink fragment is 2.5 x 0.5 x 0.2 cm. The right side is identified by a clip and this region is inked blue. The specimen is totally submitted in cassette labeled 6AFS.
Part 7 is labeled with the patient's name, initials, xx and "right superior margin". It consists of two fragments of tan-pink tissue measuring 1.1 x 0.5 x 0.3 and 1.7 x 0.3 x 0.3 cm. The right side is identified by double clips and one clip identifies external margin. These regions are inked blue. The specimen is totally submitted in a cassette labeled 7AFS.
Part 8 is labeled with the patient's name, initials, xx and "left superior". It consists of pink to tan fragment, 3.5 x 0.4 x 0.2 cm. A clip identifies the left side and this region is inked blue. The specimen is totally submitted in

RAOPERATIVE CONSULTATION:

4AFS: RIGHT LATERAL MARGIN (frozen section)
A. BENIGN.
B. NO TUMOR SEEN (.)
5AFS: LEFT LATERAL n section)
A. BENIGN.
B. NO TUMOR SEEN ()
6AFS: INFERIOR MAR tion)

[page 4 of 6]
A. BENIGN.
B. NO TUMOR SEEN ()
7AFS: RIGHT SUPERIOR (en section)
A. BENIGN.
B. NO TUMOR SEEN ()
8AFS: LEFT SUPERIOR (section)
A. BENIGN.
B. NO TUMOR SEEN. ()

COPIC:

Microscopic examination substantiates the above diagnosis. One H&E recut was performed on 3F.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined

the [REDACTED], Department of Pathology, as required by the [REDACTED]

regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical

testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory

have been established and verified for accuracy and precision.

Additional

information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - LARYNX RESECTIONS

TYPE OF LARYNGECTOMY: Total

TUMOR LATERALITY: Bilateral

ATTACHED STRUCTURES: Tracheotomy, Thyroid, Skin

TUMOR LOCATION/SEGMENT: Supraglottic

TUMOR SIZE: Maximum dimension: 4.5 cm

HISTOLOGIC TYPE OF TUMOR: Squamous cell carcinoma

HISTOLOGIC GRADE: Moderately differentiated

STRUCTURES INVOLVED BY TUMOR: False cord, Epiglottis, Pre-epiglottic

space

LYMPH NODES: Lymph nodes positive, Right: 0

Total number of right sided lymph nodes examined: 61

Lymph nodes positive, Left: 0

Total number of left sided lymph nodes examined: 36

EXTRACAPSULAR SPREAD OF LYMPH NODE METASTASES

No

INTRA-PERINEURAL INVASION: Absent

VASCULAR INVASION: No

SURGICAL MARGIN INVOLVEMENT: Free (2 mm or more)

T STAGE, PATHOLOGIC: Supraglottis, pT3

N STAGE, PATHOLOGIC: pN0

[page 5 of 6]
M STAGE, PATHOLOGIC: pMX

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: ck Level 2,3, and 4
Taken: [REDACTED] 00:00 Received: [REDACTED] 07:49
Stain/chn ock

H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J
H&E x 1 K
H&E x 1 L
H&E x 1 M
H&E x 1 N
H&E x 1 O
H&E x 1 P
H&E x 1 Q
H&E x 1 R
H&E x 1 S
H&E x 1 T

Part 2: ls 2,3, and 4
Taken: [REDACTED] Received: [REDACTED]
Stain/chn

H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J
H&E x 1 K
H&E x 1 L
H&E x 1 M
H&E x 1 N
H&E x 1 O

Part 3:
Taken: [REDACTED] 00:00 Received: [REDACTED]
Stain/chn ock

H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J

[page 6 of 6]
H&E x 1 K
H&E x 1 L
H&E x 1 M
H&E x 1 O
H&E x 1 P
H&E x 1 Q
H&E x 1 R
H&E x 1 S
H&E Recut x 1 FDC
H&E x 1 FDC
H&E x 1 NDC

Margi

H&E x 1 AFS
argin

H&E x 1 AFS
n Cli

H&E x 1 AFS
Marg p Far Right

H&E x 1 AFS
Margi

H&E x 1 AFS
TC1

Source: NCI Genomic Data Commons file acf31bd8-7714-46be-a046-d188796a2454 (TCGA-CN-5356.92475B34-D426-496C-B41D-932A3F8ED65F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).